CCDI case PBCKJA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/817737a4-963a-4c38-a6c4-7c7f9ed90ab0

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Infantile fibrosarcoma: ICD-O-3 morphology code: 8814/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 0.2 years (83 days).

Biospecimens (3 samples)
- Sample 0DU7ZR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU808: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU818: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
